Surgical pathology report (de-identified scan), TCGA case TCGA-G6-A8L8, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Roswell Park, specimen TCGA-G6-A8L8-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, clear cell 8310/3
Site B Kidney NOS C64.9
JW 11/24/13

SPECIMENS:

A. RIGHT RADICAL NEPHRECTOMY

SPECIMEN(S):

A. RIGHT RADICAL NEPHRECTOMY

DIAGNOSIS:

RIGHT KIDNEY, RADICAL NEPHRECTOMY:

- RENAL CELL CARCINOMA, CLEAR CELL TYPE, FUHRMAN NUCLEAR GRADE 2.
- TUMOR SIZE 5.1 X 3.5 X 2.8 CM.
- NO PERINEPHRIC TISSUE EXTENSION IDENTIFIED.
- SURGICAL RESECTION MARGINS, NEGATIVE FOR TUMOR.
- A SMALL LEIOMYOMA IN RENAL PARENCHYMA, 0.4 CM IN SIZE.
- ATTACHED ADRENAL GLAND SHOWING CORTICAL NODULAR HYPERPLASIA, NEGATIVE FOR TUMOR.

SYNOPTIC REPORT - KIDNEY (PARTIAL OR RADICAL)

Specimen Type: Radical nephrectomy

With adrenal gland

Laterality: Right

Tumor Site: Upper pole

Focality: Unifocal

Tumor Size (largest tumor if multiple): Greatest dimension: 5.1cm

Additional dimensions: 3.5cm x 2.8cm

Macroscopic Extent of Tumor: Tumor limited to kidney

WHO CLASSIFICATION

Clear cell renal cell carcinoma 8310/3

Histologic Grade (Fuhrman Nuclear Grade): G2: Nuclei slightly irregular, approximately 15 u; nucleoli evident

Invasion of Vascular/Lymphatic: Absent

Perinephric Tissue Invasion: Absent

Margins: Margins uninvolved by invasive carcinoma

Adrenal Gland: Uninvolved by tumor

Regional Lymph Nodes: None sampled

Additional Findings: Interstitial disease

type:: interstitial chronic inflammation

Pathological Staging (pTNM): pT 1b N X M X

GROSS DESCRIPTION:

A. RIGHT RADICAL NEPHRECTOMY

Received fresh with matching patient name and medical record number is a kidney with peri-renal fat and adrenal weighing 341 grams and measuring 16 x 9 x 6 cm overall. The kidney proper measures 12.5 x 6.5 x 5.0 cm. The outer surface is inked and the kidney is bivalved to reveal tumor in the upper pole of the kidney measuring 5.1 x 3.5 x 2.8 cm. The cut surface of the tumor appears pale yellow to gray-white. The tumor is very close to the renal capsule but with an intact capsule. The tumor is approximately 1.5 cm away from the renal pelvis. The adrenal gland measures 6.5 x 3.0 x 1.0 cm. The blood vessels at the hilum measures approximately 0.7 cm in length and 0.5 cm in diameter. The ureter measures 5.0 cm in length and 0.4 cm in diameter. A small portion of the tumor is taken for tissue procurement. The kidney is serially sectioned and two small gray-white lesions measuring 0.2 cm is noted, one is approximately 1.0 cm from the larger tumor and the other one is close to the lower pole of the kidney. The hilar fat is dissected and no lymph nodes are identified. The adrenal gland is serially sectioned to reveal a 0.5 cm nodule with bright yellow cut surface. Representative sections are submitted for microscopic examination as follows:

A1: blood vessel and ureter margin

A2: tumor in relation to the renal capsule

[page 2 of 2]
- A3: tumor in relation to normal-appearing kidney
- A4: tumor in relation to the adrenal
- A5-A7: tumor in relation to the peri-renal fat and inked margin
- A8: additional section of tumor
- A9: normal-appearing kidney
- A10: unremarkable renal pelvis and the kidney section with small nodule close to the larger lesion
- A11: small nodule in the lower pole of the kidney
- A12: section of adrenal
- A13: section of adrenal nodule

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Right renal mass

Gross Dictation: Pathologist,
Microscopic/Diagnostic Dictation: .. Pathologist
Final Review:.. Pathologist.
Final: Pathologist,

Source: NCI Genomic Data Commons file 1ff2b29b-efdf-4398-9cdd-4ddbea944377 (TCGA-G6-A8L8.8CE40BF4-ED9F-4F69-A831-E19099D31F0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).